Somatic mutation profile of tumor specimen TCGA-BK-A0CB-01A (aliquot TCGA-BK-A0CB-01A-32D-A10B-09) from TCGA case TCGA-BK-A0CB, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IIIC; Tumor grade: G2; Age at diagnosis: 60.0 years (21,930 days).
Specimen TCGA-BK-A0CB-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 064e1da6-a23c-49d8-8ff1-e5ba2903874c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BK-A0CB-11A (Solid Tissue Normal), aliquot TCGA-BK-A0CB-11A-33D-A10B-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c421470d-96bf-42ed-8a94-4167b9bc5f7b

The open-access MAF lists 54 somatic variants for this specimen: 42 protein-altering or splice-affecting, 12 silent.
By variant classification: Missense Mutation 34, Silent 12, Nonsense Mutation 4, Frame Shift Ins 1, In Frame Del 1, Frame Shift Del 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARID1A | c.2077C>T p.R693* | Nonsense Mutation (SNP) | VAF 60/171 reads (35%) | hotspot (GDC flag); catalogued as COSV61375361; called by muse, mutect2, varscan2
- CTNNB1 | c.95A>G p.D32G | Missense Mutation (SNP) | VAF 24/68 reads (35%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as rs121913396, COSV62688001, COSV62688037, COSV62688249; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.1624G>A p.E542K | Missense Mutation (SNP) | VAF 14/49 reads (29%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.912); catalogued as rs121913273, CM153078, COSV55873227, COSV55894248; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- PTEN | c.388C>G p.R130G | Missense Mutation (SNP) | VAF 33/94 reads (35%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121909224, CM094223, CM971273, COSV64288384, COSV64288463, COSV64297940, COSV64311187; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABCA3 | c.3632C>T p.T1211M | Missense Mutation (SNP) | VAF 33/100 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.418); catalogued as rs777536136, COSV57053612; called by muse, mutect2, varscan2
- ARHGEF11 | c.136C>T p.R46C | Missense Mutation (SNP) | VAF 20/65 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1347868807, COSV63810156; called by muse, mutect2, varscan2
- BAHD1 | c.451C>T p.P151S | Missense Mutation (SNP) | VAF 14/23 reads (61%) | SIFT tolerated (0.66); PolyPhen benign (0.005); catalogued as COSV69083970; called by muse, varscan2
- CDH7 | c.1019G>A p.R340Q | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.765); catalogued as rs1420186009, COSV59886253; called by muse, mutect2, varscan2
- CHD4 | c.3368C>A p.A1123D (on ENST00000357008 / NM_001363606.2; = p.A1136D on NM_001273.5) | Missense Mutation (SNP) | VAF 51/127 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV58901144; called by muse, mutect2, varscan2
- CHRNA2 | c.203G>A p.R68Q | Missense Mutation (SNP) | VAF 37/99 reads (37%) | SIFT tolerated (0.55); PolyPhen benign (0.166); catalogued as rs548268816, COSV53556857, COSV53557723; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CLTCL1 | c.4888G>T p.A1630S (on ENST00000427926 / NM_007098.4; = p.A1573S on NM_001835.4) | Missense Mutation (SNP) | VAF 30/121 reads (25%) | SIFT tolerated (0.27); PolyPhen benign (0.005); catalogued as COSV53205787; called by muse, mutect2, varscan2
- CLUH | c.1207G>A p.G403S (on ENST00000435359; = p.G441S on NM_015229.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 19/44 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1373639535, COSV70930218; called by muse, mutect2
- COX6B2 | c.216G>A p.V72= | Splice Region (SNP) | VAF 32/98 reads (33%) | catalogued as COSV58483936; called by muse, mutect2, varscan2
- CPT1A | c.2234C>T p.T745M | Missense Mutation (SNP) | VAF 30/87 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs758127254, COSV55756117; called by muse, mutect2, varscan2
- ELP5 | c.353C>T p.P118L | Missense Mutation (SNP) | VAF 51/135 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.129); catalogued as COSV59708690; called by muse, mutect2, varscan2
- ERC2 | c.1795C>T p.R599C | Missense Mutation (SNP) | VAF 46/105 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs746095506, COSV55616033; called by muse, mutect2, varscan2
- FAT2 | c.5891A>G p.K1964R | Missense Mutation (SNP) | VAF 11/61 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.042); catalogued as COSV55819667; called by muse, mutect2, varscan2
- GPR182 | c.725C>T p.A242V | Missense Mutation (SNP) | VAF 37/87 reads (43%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.538); catalogued as rs1281736951, COSV55626173; called by muse, mutect2, varscan2
- HEXB | c.422C>T p.P141L | Missense Mutation (SNP) | VAF 22/188 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV54667757; called by muse, mutect2, varscan2
- HPN | c.640C>G p.R214G | Missense Mutation (SNP) | VAF 29/84 reads (35%) | SIFT tolerated (0.06); PolyPhen benign (0.06); catalogued as rs1313009188, COSV52883591; called by muse, mutect2, varscan2
- KIAA0319 | c.2396C>T p.S799L | Missense Mutation (SNP) | VAF 20/50 reads (40%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.68); catalogued as rs764238150, COSV65498329; called by muse, mutect2, varscan2
- KMT2B | c.374G>A p.G125D | Missense Mutation (SNP) | VAF 80/239 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV52890563; called by muse, mutect2, varscan2
- MAP7D3 | c.1199C>A p.A400E | Missense Mutation (SNP) | VAF 18/74 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.075); catalogued as COSV60170969; called by muse, mutect2, varscan2
- MTMR12 | c.1925G>A p.R642H | Missense Mutation (SNP) | VAF 35/89 reads (39%) | SIFT tolerated (0.33); PolyPhen probably damaging (0.999); catalogued as rs754133953, COSV53784261; called by muse, mutect2, varscan2
- NDST4 | c.756del p.F253Lfs*4 | Frame Shift Del (DEL) | VAF 23/96 reads (24%) | catalogued as rs1218019823, COSV52119807, COSV52136259; called by mutect2, pindel, varscan2
- NDST4 | c.659G>A p.W220* | Nonsense Mutation (SNP) | VAF 15/64 reads (23%) | catalogued as rs1365968691, COSV52119814; called by muse, varscan2
- NLRP8 | c.1064C>T p.P355L | Missense Mutation (SNP) | VAF 40/99 reads (40%) | SIFT tolerated (0.48); PolyPhen benign (0.031); catalogued as rs532289570, COSV52587105; called by muse, mutect2, varscan2
- OR4K5 | c.562G>T p.A188S | Missense Mutation (SNP) | VAF 27/262 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.594); catalogued as COSV60003510; called by muse, mutect2, varscan2
- OR8H2 | c.896A>T p.N299I | Missense Mutation (SNP) | VAF 26/74 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.127); catalogued as COSV57944552; called by muse, mutect2, varscan2
- PNPLA3 | c.628C>T p.L210F | Missense Mutation (SNP) | VAF 67/196 reads (34%) | SIFT tolerated (0.15); PolyPhen benign (0.007); catalogued as COSV53378262; called by muse, mutect2, varscan2
- PTEN | c.271G>T p.E91* | Nonsense Mutation (SNP) | VAF 34/127 reads (27%) | catalogued as rs1554898062, COSV64292991, COSV64310647; called by muse, mutect2, varscan2
- RDH13 | c.230C>T p.A77V (on ENST00000415061 / NM_001145971.2; = p.A6V on NM_138412.4) | Missense Mutation (SNP) | VAF 56/140 reads (40%) | SIFT tolerated (0.24); PolyPhen benign (0.005); catalogued as rs199679574, COSV52560871; called by muse, mutect2, varscan2
- RMND1 | c.1156T>C p.Y386H | Missense Mutation (SNP) | VAF 47/147 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs528012570, COSV60550560; called by muse, mutect2, varscan2
- RNF19A | c.2179C>A p.H727N | Missense Mutation (SNP) | VAF 45/136 reads (33%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.954); catalogued as COSV61993185, COSV61993640; called by muse, mutect2, varscan2
- SPTA1 | c.1574T>A p.F525Y | Missense Mutation (SNP) | VAF 24/61 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV63753013; called by muse, mutect2, varscan2
- TMEM62 | c.1641G>A p.M547I | Missense Mutation (SNP) | VAF 119/343 reads (35%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as COSV53041105; called by muse, mutect2, varscan2
- UBA52 | c.124C>G p.R42G | Missense Mutation (SNP) | VAF 40/120 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.071); catalogued as COSV55889549; called by muse, mutect2, varscan2
- WAS | c.655G>T p.G219* | Nonsense Mutation (SNP) | VAF 66/179 reads (37%) | catalogued as COSV64997142; called by muse, mutect2, varscan2
- ZMIZ2 | c.870G>T p.Q290H | Missense Mutation (SNP) | VAF 21/62 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV54808249; called by muse, mutect2, varscan2
- ZPBP | c.806T>A p.F269Y | Missense Mutation (SNP) | VAF 34/90 reads (38%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.545); catalogued as rs747400544, COSV50425381; called by muse, mutect2, varscan2
- ARID1A | c.3001dup p.S1001Ffs*6 | Frame Shift Ins (INS) | VAF 56/144 reads (39%) | called by mutect2, pindel, varscan2
- VCAM1 | c.1813_1842del p.L605_K614del | In Frame Del (DEL) | VAF 15/62 reads (24%) | called by mutect2, pindel, varscan2
- DCAF10 | c.1560G>T p.V520= | Silent (SNP) | VAF 27/94 reads (29%) | catalogued as COSV54288270; called by muse, mutect2, varscan2
- FGD6 | c.669G>A p.A223= | Silent (SNP) | VAF 28/92 reads (30%) | catalogued as rs767628590, COSV59693282; called by muse, mutect2, varscan2
- FLRT2 | c.1833C>T p.S611= | Silent (SNP) | VAF 14/38 reads (37%) | catalogued as COSV58141451; called by muse, mutect2, varscan2
- KCNV1 | c.297C>T p.N99= | Silent (SNP) | VAF 21/45 reads (47%) | catalogued as COSV52086110; called by muse, mutect2, varscan2
- MADD | c.1503C>T p.N501= | Silent (SNP) | VAF 54/149 reads (36%) | catalogued as rs1371179363, COSV60621480; called by muse, mutect2, varscan2
- MN1 | c.2697C>T p.S899= | Silent (SNP) | VAF 17/45 reads (38%) | catalogued as COSV56558378; called by muse, mutect2, varscan2
- MUSK | c.1674G>A p.P558= | Silent (SNP) | VAF 77/224 reads (34%) | catalogued as rs541645382, COSV51878149; ClinVar: likely benign; called by muse, mutect2, varscan2
- SCAF8 | c.1944C>G p.A648= | Silent (SNP) | VAF 41/120 reads (34%) | catalogued as rs758502107, COSV63200226, COSV63200268; called by muse, mutect2, varscan2
- TMIE | c.408A>T p.T136= | Silent (SNP) | VAF 91/284 reads (32%) | catalogued as COSV58405733; called by muse, mutect2, varscan2
- TYW3 | c.741T>C p.D247= | Silent (SNP) | VAF 21/62 reads (34%) | catalogued as COSV63802849; called by muse, mutect2, varscan2
- UGT1A10 | c.78G>A p.G26= | Silent (SNP) | VAF 42/124 reads (34%) | catalogued as rs767881078, COSV60836404; called by muse, mutect2, varscan2
- XIRP2 | c.7494C>T p.C2498= (on ENST00000628543; = p.C2673= on NM_152381.6) | Silent (SNP) | VAF 4/10 reads (40%) | catalogued as rs372125508; called by muse, mutect2, varscan2
